Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVZ-01A (Primary Tumor).

DIAGNOSIS:

Liver, right, posterior sectionectomy:

Hepatocellular carcinoma, S6/7

- 1) Post-chemocmbolization status: absent
- 2) Size of tumor: 3.2x2.3x3.0cm
- 3) Gross type: nodular with perinodal extension
- 4) Satellite nodule: absent
- 5) Histologic type: pseudoglandular and trabecular
- 6) Cell type: classical
- 7) Edmondson and Steiner's histologic grade:
- The worst differentiation: 3
- The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: complete
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 0.6cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1), (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, inactive, HBV-associated
- b) Dysplasia: absent

ICD O-3
Carcinoma, hepatocellular
N65 8170/3
Site: Liver C22.0
Q4 4/23/14

Soft tissue, diaphragm, "intraparenchymal mass", biopsy:

Epithelial cyst,
suggestive of ciliated foregut cyst

Source: NCI Genomic Data Commons file 605a1019-5200-47b3-a846-089f68f13f78 (TCGA-DD-AAVZ.1146563E-D472-4EFF-8753-7CEEE2F74C12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).